TCGA case TCGA-33-4587 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46cc3a2b-91c9-4a74-8989-992585634b87

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 1,656 days (4.5 years).

Diagnoses (1)
1. Squamous cell carcinoma, small cell, nonkeratinizing: ICD-O-3 morphology code: 8073/3; ICD-10 code: C34.2; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 63.1 years (23,062 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 63 days; Days to treatment end: 63 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 63 days; Days to treatment end: 63 days; Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 93 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 154 days; Number of cycles: 4; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 154 days; Number of cycles: 4; Prescribed dose: 4; Prescribed dose units: mg/kg/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 93 days; Number of cycles: 1; Prescribed dose: 1; Prescribed dose units: g/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 154 days; Number of cycles: 4; Prescribed dose: 6; Prescribed dose units: mg/mL; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,656 days (4.5 years); Disease response: With Tumor.

Other clinical attributes
- DLCO (% of predicted): 111; FEV1/FVC after bronchodilator (%): 91; FEV1/FVC before bronchodilator (%): 76; FEV1 after bronchodilator (% of reference): 73; FEV1 before bronchodilator (% of reference): 75.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 2003.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-33-4587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-33-4587-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 10.
  Slide TCGA-33-4587-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 10.
- Sample TCGA-33-4587-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 1.1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Small Cell Squamous Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Middle; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 3; Pharmaceutical therapy drug name: adriamycin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: etoposide (VP-16).
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 4: Regimen number: 2.
- Drug treatment 6: Regimen number: 3; Pharmaceutical therapy drug name: cytoxan.
- Follow-up form: Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,656 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,656 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,656 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-33-4587-01A-11D-2121-01): tumor purity 0.88, ploidy 3.91, whole-genome doublings 1.
